Surgical pathology report (de-identified scan), TCGA case TCGA-85-8071, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8071-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

Case ID	OpenClinica ID	Gross Description	Microscopic Description	Diagnosis Details	Comments

[page 2 of 2]
Formatted Path Report
LUNG TISSUE CHECKLIST
Specimen type: Pulmonectomy
Tumor site: Lung
Tumor size: 2 x 1.2 x 0.7 cm
Histologic type: Squamous cell carcinoma
Histologic grade: Moderately differentiated
Tumor extent: Tumor in main bronchus
Other tumor nodules: Not specified
Lymph nodes: 2/6 positive for metastasis (Intrathoracical 2/6)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

Laterality
Right-upper

Excision date

Source: NCI Genomic Data Commons file e0975448-47a9-4295-a637-84df6f004e1b (TCGA-85-8071.8789B4D7-E9B3-475D-B805-1096D57BA266.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).